CTSP case CTSP-B02C — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa7c507e-0d0f-49aa-a497-507a43bdeed2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Dead; Days to death: 214 days; Year of death: 2012; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 67.0 years (24,484 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 214 days; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk.

Biospecimens (1 sample)
- Sample DLBCL11330-sample: Sample type: Tumor; Tissue type: Tumor.
